Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A4YX, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A4YX-01A (Primary Tumor).

Patient: XXX

PESEL: XXX

Age:

Gender: M

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion): Stomach carcinoma

Date of admission:

(urgency: Standard)

ICD-0-3

Adenocarcinoma, NOS 8140/3

CQCF Site: Stomach, fundus c16.1

Path Stomach, NOS c16.9

11/4/12

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathological Diagnosis:

Examination performed on: /

Adenocarcinoma male differentiatum ventriculi. Stomach adenocarcinoma poorly differentiated. Cancer metastases in lymph nodes NO I/XIX. G3, pT3, pN1, Intestinal type: sec. Lauren. (8140/3 T-63000)*

Macroscopic description:

Specimen consisting of the stomach, having been cut out along the greater curvature, sized 21.5 x 18 cm with the omentum sized 35 x 18 cm.

Cauliflower-shaped tumour on the posterior sized 9.5 x 6.5 x 3.1 cm. Distance from the proximal end: 1.3 cm, from distal end: 9.5 cm.

Microscopic description:

Adenocarcinoma male differentiatum.

Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae periventricularis.

Surgical incision lines clear of cancerous invasion (proximal line under microscopic examination 0.4 cm).

Emboliae carcinomatosa vasorum. Omentum sine metastasibus. LYMPH NODES:

- cardia: metastases carcinomatosa in lymphonodo No (I/I). Infiltratio carcinomatosa capsulae lymphonodo.
- lesser curvature: lymphonodulitis reactiva (No VII)
- greater curvature: lymphonodulitis reactiva (No VII)
- pyrolic: lymphonodulitis reactiva (No II).

Assistant:

Pathologist

Edited by

Result of immunohistochemical examination

Examination performed on:

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody.

Positive reaction in invasive cancerous cells (Score = 3+)

Assistant:

Edited by

HIO/AA Discrepancy		
Cause of Death		
Review of Immunohistochemistry		

Source: NCI Genomic Data Commons file 599921f1-eaaa-4104-9a23-a5f4c642769b (TCGA-D7-A4YX.B7CAF119-E179-41C6-B938-26D9DF84376B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).